CCDI case PBCCLA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/41b05038-ad9e-4c3b-a28e-dd605f7c23ce

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.8 years (3,938 days).

Biospecimens (3 samples)
- Sample 0DOO1I: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DOO1K: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DOOCU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
